Gene-level copy-number profile of tumor specimen TCGA-B6-A0I9-01A from TCGA case TCGA-B6-A0I9, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 62.4 years (22,798 days).
Specimen TCGA-B6-A0I9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.947bb0f4-c580-43da-967d-1026abbd4e32.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A0I9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a6a606d4-2cde-4633-85b5-62f7371c2466

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,982; copy number 2: 16,076; copy number 3: 26,857; copy number 4: 8,478; copy number 5: 1,973; copy number 6: 3,153; copy number 7: 538; copy number 8: 61; copy number 9: 124; copy number 10: 14; copy number 11: 17; copy number 12: 232; copy number 13: 16; copy number 14: 81; copy number 15: 33; copy number 16: 43; copy number 17: 60; copy number 18: 6; copy number 19: 1; copy number 20: 24; copy number 21: 9; copy number 22: 1; copy number 27: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A0I9-01A-11D-A036-01): tumor purity 0.61, ploidy 3.05, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,286 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:14,764,952–15,142,157, 10 genes, copy number 10: AC090957.1, AC087591.1, LINC02011, FGD5, FGD5-AS1, NR2C2, MRPS25, RBSN, AC090954.1, RPS3AP53.
- chr7:12,211,270–23,532,041, 144 genes, copy number 7–20 (within-gene range 2–20) (broad region; genes not listed).
- chr7:37,848,597–38,631,420, 29 genes, copy number 7 (within-gene range 4–7): NME8, SFRP4, STARD3NL, TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1, AMPH, RN7SL83P.
- chr9:103,689,473–103,689,577, 1 gene, copy number 8: RNA5SP291.
- chr9:104,970,593–105,239,221, 3 genes, copy number 7 (within-gene range 3–7): CT70, AL591506.1, RN7SKP191.
- chr9:117,276,985–117,277,286, 1 gene, copy number 19: RN7SKP125.
- chr11:32,052,843–32,105,722, 5 genes, copy number 7 (within-gene range 2–7): AL035078.3, AL035078.2, U3, EIF4A2P5, RCN1.
- chr11:47,841,324–48,628,493, 26 genes, copy number 9: YPEL5P2, AC023232.1, PTPRJ, PTPRJ-AS1, MIR3161, OR4B1, OR4B2P, OR4X2, OR4X1, OR4S1, OR4C3, OR4C4P, OR4C5, OR4C2P, OR4C10P, OR4C9P, OR4R1P, OR4A47, OR4A48P, OR4A46P, OR4A40P, OR4A43P, OR4A45P, OR4A41P, OR4A42P, OR4A44P.
- chr11:66,330,241–68,449,275, 119 genes, copy number 12–18 (broad region; genes not listed).
- chr11:68,870,664–71,252,577, 61 genes, copy number 8–16 (within-gene range 1–16) (broad region; genes not listed).
- chr11:74,454,841–74,498,533, 6 genes, copy number 12: KCNE3, AP001372.3, CYCSP27, AP001372.4, LIPT2, AP001372.2.
- chr11:75,069,243–75,351,705, 15 genes, copy number 14: AP003175.1, OR2AT2P, NPM1P50, OR2AT4, AP001972.4, SLCO2B1, OR2AT1P, AP001972.3, ZDHHC20P3, TPBGL, ARRB1, AP001972.1, AP001972.5, AP001972.2, MIR326.
- chr11:75,815,210–78,188,626, 64 genes, copy number 7–10 (within-gene range 4–10) (broad region; genes not listed).
- chr11:78,579,255–79,989,630, 11 genes, copy number 7–8: RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1, AP001547.1, MIR708, MIR5579, AP001978.1, AP001541.1, AP001284.1.
- chr11:81,015,849–82,718,299, 8 genes, copy number 12–22 (within-gene range 5–22): AP003398.2, AP003464.1, MTND4LP18, MTND6P25, MIR4300HG, AP002802.2, MIR4300, AP002802.1.
- chr11:83,455,012–85,627,922, 1 gene, copy number 7 (within-gene range 2–7): DLG2.
- chr11:84,545,131–98,945,079, 276 genes, copy number 7–13 (broad region; genes not listed).
- chr11:99,120,176–99,120,490, 1 gene, copy number 13: RN7SKP53.
- chr11:126,121,889–126,440,344, 18 genes, copy number 9 (within-gene range 2–9): AP000821.2, AP001893.3, AP001893.2, RPUSD4, AP001893.1, FAM118B, RNU4-86P, RN7SL351P, SRPRA, FOXRED1, RPL35AP26, TIRAP, AP001318.1, AP001318.2, DCPS, GSEC, ST3GAL4, AP001318.3.
- chr11:128,095,758–128,183,671, 1 gene, copy number 14: LINC02725.
- chr13:41,905,118–44,030,461, 35 genes, copy number 7–15: RNU6-74P, KARS1P1, VWA8-AS1, RPS28P8, DGKH, AL157932.1, MAPK6P3, CHCHD2P11, FHP1, AKAP11, LINC02341, FABP3P2, TNFSF11, FAM216B, LINC01050, LINC00428, EPSTI1, ZDHHC4P1, DNAJC15, LINC00400, AL138709.1, ENOX1, RPL36P19, ENOX1-AS2, ENOX1-AS1, AL161714.1, AL162713.2, AL162713.1, CCDC122, AL512506.1, LACC1, AL512506.3, AL512506.2, NRAD1, DGKZP1.
- chr15:47,184,101–53,129,698, 140 genes, copy number 7–8 (within-gene range 2–8) (broad region; genes not listed).
- chr15:66,278,498–66,491,544, 10 genes, copy number 7 (within-gene range 3–7): AC055855.2, DIS3L, AC055855.1, TIPIN, SCARNA14, Y_RNA, RPL9P25, MAP2K1, ATP5MFP6, RPL35AP32.
- chr15:83,654,088–84,080,097, 6 genes, copy number 7 (within-gene range 3–7): ADAMTSL3, RNU6-401P, TUBAP4, RNU6-1339P, AC027807.2, AC027807.1.
- chr15:85,255,369–85,330,334, 1 gene, copy number 8 (within-gene range 4–8): ADAMTS7P4.
- chr15:85,380,596–85,415,633, 3 genes, copy number 8: MIR7706, RNU7-79P, FABP5P9.
- chr15:86,295,649–86,317,173, 1 gene, copy number 8 (within-gene range 3–8): AGBL1-AS1.
- chr17:36,684,754–38,729,795, 56 genes, copy number 9–15: AC243830.3, AC243830.1, LHX1-DT, LHX1, AC243773.1, AATF, AC243773.2, AC244093.4, MIR2909, AC244093.3, AC244093.5, ACACA, AC244093.1, HMGB1P24, AC244093.2, C17orf78, AC243654.3, TADA2A, AC243654.1, AC243654.2, DUSP14, SYNRG, AC243585.2, DDX52, MIR378J, AC243571.2, AC243585.1, HNF1B, AC243571.1, YWHAEP7, RNU6-489P, TBC1D3K, 5S_rRNA, TBC1D3L, TBC1D3D, TBC1D3C, AC233968.1, Y_RNA, TBC1D3E, RNA5SP526, TBC1D3, NPEPPSP1, Y_RNA, MRPL45, GPR179, SOCS7, ARHGAP23, AC244153.1, SRCIN1, AC006449.1, EPOP, MIR4734, AC006449.6, AC006449.2, MLLT6, AC006449.3.
- chr17:38,800,441–40,195,656, 68 genes, copy number 9–27 (within-gene range 3–27) (broad region; genes not listed).
- chr17:67,377,281–67,697,261, 1 gene, copy number 12 (within-gene range 4–12): PITPNC1.
- chr17:67,611,277–68,955,392, 41 genes, copy number 12: AC079331.2, AC079331.1, AC079331.3, NOL11, SNORA38B, RPSAP67, RPL17P41, BPTF, AC134407.1, AC134407.2, AC134407.3, RN7SL622P, C17orf58, KPNA2, FBXO36P1, AC145343.1, LINC00674, LRRC37A16P, AC005332.6, AC005332.3, AC005332.5, SH3GL1P3, RDM1P3, AC005332.7, AC005332.2, ARHGAP27P2, AC005332.4, AMZ2, AC005332.1, ARSG, SLC16A6, AC007780.1, WIPI1, MIR635, PRKAR1A, FAM20A, AC079210.1, LINC01482, AC011591.2, AC011591.1, ABCA8.
- chr20:34,516,414–35,959,472, 59 genes, copy number 7–17 (within-gene range 3–17): DYNLRB1, MAP1LC3A, PIGU, AL118520.1, NCOA6, TP53INP2, AL109824.1, HMGB3P1, GGT7, ACSS2, GSS, MYH7B, MIR499A, MIR499B, TRPC4AP, RNU6-407P, EDEM2, AL135844.1, PROCR, AL356652.1, RNA5SP483, MMP24OS, MT1P3, MMP24, AL121753.2, AL121753.1, EIF6, FAM83C-AS1, FAM83C, UQCC1, GDF5-AS1, GDF5, MIR1289-1, CEP250, CEP250-AS1, FO393401.1, C20orf173, ERGIC3, RPL36P4, FER1L4, RPL37P1, SPAG4, CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12, NFS1, ROMO1, RBM39, RPF2P1, U6, PHF20, COX7BP2, Y_RNA, HIGD1AP16, RNU4-40P, RNU6-937P, SCAND1.
- chr20:57,105,741–59,259,113, 65 genes, copy number 12–21 (within-gene range 6–21) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,982. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
